Gene-level copy-number profile of tumor specimen TCGA-50-5946-02A from TCGA case TCGA-50-5946, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 62.6 years (22,852 days).
Specimen TCGA-50-5946-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.6f6a5220-5d0c-4954-a95e-f25060179734.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,845 have no estimate.
https://portal.gdc.cancer.gov/files/09078e31-3fa7-4b1f-ad8f-01d2941f872b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 3,228; copy number 2: 26,287; copy number 3: 17,240; copy number 4: 5,590; copy number 5: 1,551; copy number 6: 218; copy number 7: 657.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-5946-02A-11D-2085-01): tumor purity 0.9, ploidy 2.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,929,457–21,995,301, 3 genes: ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,426 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,748,002–144,642,372, 92 genes, copy number 5 (broad region; genes not listed).
- chr1:144,887,265–158,331,531, 621 genes, copy number 5 (broad region; genes not listed).
- chr1:209,583,714–209,806,175, 10 genes, copy number 6: CAMK1G, LAMB3, MIR4260, HSD11B1-AS1, G0S2, HSD11B1, ADORA2BP1, TRAF3IP3, C1orf74, IRF6.
- chr5:892,884–45,696,498, 673 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr7:549,197–23,897,335, 366 genes, copy number 5 (broad region; genes not listed).
- chr17:33,565,764–33,624,122, 1 gene, copy number 5: AC011824.2.
- chr17:73,831,572–78,846,868, 224 genes, copy number 5 (broad region; genes not listed).
- chr17:78,855,478–78,855,844, 1 gene, copy number 5: AC022966.1.
- chr19:14,689,801–21,720,035, 373 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr19:23,380,317–28,727,680, 53 genes, copy number 5 (within-gene range 4–5): BNIP3P8, CDC42EP3P1, LINC01224, VN1R92P, AC074140.1, ZNF725P, ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1, ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1.
- chr21:8,762,386–9,129,752, 12 genes, copy number 5: CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.

Autosomal genes at a single copy (total copy number 1): 3,228. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
